Somatic mutation profile of tumor specimen TCGA-UF-A71A-06A (aliquot TCGA-UF-A71A-06A-11D-A391-08) from TCGA case TCGA-UF-A71A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 67.4 years (24,623 days).
Specimen TCGA-UF-A71A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05e57288-1952-49e5-8e56-ae311bc83c31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A71A-10A (Blood Derived Normal), aliquot TCGA-UF-A71A-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4a961fe-28ee-4a1b-b1c1-75af763a0b9b

The open-access MAF lists 210 somatic variants for this specimen: 154 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 49, Nonsense Mutation 10, Splice Site 8, Frame Shift Del 4, Intron 3, RNA 3, Translation Start Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, varscan2
- ADAM8 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769225852, COSV101291712; called by muse, varscan2
- ADGRV1 | c.10069A>G p.I3357V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV101316300; called by muse, mutect2, varscan2
- AHNAK | c.16691C>G p.P5564R | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99948896; called by muse, mutect2, varscan2
- AL592490.1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101308258; called by muse, mutect2, varscan2
- ALS2 | c.4798G>A p.D1600N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51894843; called by muse, mutect2, varscan2
- ALX4 | c.1060G>T p.G354W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100241196; called by muse, mutect2, varscan2
- ANKRD44 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV56549849, COSV56553196; called by muse, mutect2, varscan2
- APP | c.1738A>G p.M580V | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs533667466, COSV100696129; called by muse, mutect2, varscan2
- ARHGAP4 | c.1836G>C p.E612D | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV100509624; called by muse, mutect2, varscan2
- ASXL3 | c.5618C>T p.P1873L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99325980; called by muse, mutect2, varscan2
- BLZF1 | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100250755; called by muse, mutect2, varscan2
- BMF | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as rs758140624, COSV55019213, COSV99590502; called by muse, mutect2, varscan2
- C7 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV57481875; called by muse, mutect2
- C7 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs747361977; called by muse, mutect2, varscan2
- CASD1 | c.1712A>T p.Q571L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99802914; called by muse, mutect2, varscan2
- CCDC171 | c.1483A>G p.N495D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV99901561; called by muse, mutect2, varscan2
- CD200R1L | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV101236620; called by muse, mutect2, varscan2
- CDC42BPA | c.4958G>A p.G1653E (on ENST00000334218 / NM_001366019.2; = p.G1640E on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100506333; called by muse, mutect2, varscan2
- CDH11 | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.807); catalogued as COSV99219385; called by muse, mutect2, varscan2
- CENPJ | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101121557; called by muse, mutect2, varscan2
- CEP83 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs752784276, COSV100353086, COSV60407618; called by muse, mutect2, varscan2
- CNTN1 | c.998G>A p.W333* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV61641766; called by muse, mutect2, varscan2
- CNTN3 | c.2128G>A p.G710R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99725677; called by muse, mutect2, varscan2
- COL6A6 | c.4109G>A p.R1370Q | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1285891321, COSV100650703; called by muse, mutect2, varscan2
- CPSF1 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1023263626, COSV100450642, COSV58231918; called by muse, mutect2, varscan2
- CSPG4 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758235057, COSV100414001; called by muse, mutect2, varscan2
- CSRNP1 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99827027; called by muse, mutect2, varscan2
- DENND1B | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs201455013, COSV99345117; called by muse, mutect2
- DHX34 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100169829; called by muse, mutect2, varscan2
- DLG2 | c.1386G>C p.Q462H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV54697542; called by muse, mutect2, varscan2
- DNAH1 | c.2646G>T p.E882D | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV101326691; called by muse, mutect2, varscan2
- DPRX | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100934112; called by muse, mutect2, varscan2
- DTWD2 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV100407083; called by muse, mutect2
- EFNB3 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs562472485, COSV99872903; called by muse, mutect2, varscan2
- ELOVL2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100675997; called by muse, mutect2, varscan2
- ELP1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65900880; called by muse, mutect2, varscan2
- ESRRG | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1243398576, COSV100753610; called by muse, mutect2, varscan2
- F3 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); catalogued as COSV100474379; called by muse, mutect2, varscan2
- FANCM | c.5165C>T p.P1722L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV99951447; called by muse, mutect2, varscan2
- FILIP1L | c.2590C>T p.P864S (on ENST00000354552 / NM_182909.3; = p.P624S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100497223; called by muse, mutect2, varscan2
- FOXB2 | c.177C>A p.N59K | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100942371, COSV65023762; called by muse, mutect2, varscan2
- FSTL5 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100059319; called by muse, mutect2, varscan2
- GABRP | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267600549, COSV99517011; called by muse, mutect2, varscan2
- GALNT13 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101223936; called by muse, mutect2, varscan2
- GEN1 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | catalogued as COSV100438130; called by muse, mutect2, varscan2
- GLMP | c.898T>C p.C300R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99828042; called by muse, mutect2, varscan2
- GOLGA1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV101001990; called by muse, mutect2, varscan2
- GPC5 | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100995133; called by muse, mutect2
- GPC5 | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); catalogued as COSV100995131; called by muse, mutect2, varscan2
- GPR151 | c.102C>A p.D34E | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99695149; called by muse, mutect2, varscan2
- GRM3 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.061); catalogued as COSV100862733; called by muse, mutect2, varscan2
- GRM3 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.08); catalogued as COSV100862095, COSV64466532, COSV64481485; called by muse, mutect2, varscan2
- GRM5 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553571; called by muse, mutect2, varscan2
- HGF | c.1456T>A p.S486T | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99738000; called by muse, mutect2, varscan2
- HOOK1 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0.022); catalogued as COSV100969200; called by muse, mutect2, varscan2
- HOXD3 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1225066883, COSV99980317; called by muse, mutect2, varscan2
- HTR5A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1372976826, COSV55283469; called by muse, mutect2, varscan2
- IFT80 | c.1390T>G p.L464V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100425013; called by muse, mutect2, varscan2
- IGFL3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV58242939; called by muse, mutect2, varscan2
- IGSF10 | c.1490G>T p.C497F | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1367678417, COSV99191490; called by muse, mutect2, varscan2
- ITM2A | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 19/20 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100964446, COSV100964478; called by muse, mutect2, varscan2
- KCNJ1 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100131438; called by muse, mutect2, varscan2
- KDM4A | c.1163+2T>C p.X388_splice | Splice Site (SNP) | VAF 133/180 reads (74%) | catalogued as COSV100969588; called by muse, mutect2, varscan2
- KIAA1210 | c.4380T>A p.N1460K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV101274341; called by muse, mutect2, varscan2
- KIF21A | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735574; called by muse, mutect2, varscan2
- KLHL1 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 63/76 reads (83%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV64768090; called by muse, mutect2, varscan2
- KRT5 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99358203; called by muse, mutect2, varscan2
- KRTAP4-1 | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.129); catalogued as rs772650277, COSV100893538, COSV100893580; called by muse, varscan2
- LAMC1 | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV99280212; called by muse, mutect2, varscan2
- LOXL3 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs748837090, COSV99284164; called by muse, mutect2, varscan2
- LRRC4C | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV53420646, COSV99539155; called by muse, mutect2, varscan2
- MOCS3 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs187280062, COSV54868385; called by muse, mutect2, varscan2
- MYO15A | c.9979A>T p.S3327C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99233910; called by muse, mutect2, varscan2
- NAA25 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as COSV99927879; called by muse, mutect2, varscan2
- NAGLU | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs368907396; called by muse, mutect2, varscan2
- NDST4 | c.2527del p.R843Efs*22 | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | catalogued as COSV52137800; called by mutect2, pindel, varscan2
- NLRC3 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746010308, COSV57089565; called by muse, varscan2
- OR4D5 | c.230C>G p.T77R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100190132; called by muse, mutect2, varscan2
- OR51M1 | c.394T>C p.F132L | Missense Mutation (SNP) | VAF 101/192 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV100150338, COSV100150423; called by muse, mutect2, varscan2
- OR8D1 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV100766668; called by muse, mutect2, varscan2
- PAPPA2 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868658099, COSV100866982; called by muse, mutect2, varscan2
- PLB1 | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV100579614; called by muse, mutect2, varscan2
- PLXNA4 | c.5062C>A p.L1688M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100326157; called by muse, mutect2, varscan2
- PLXNA4 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV100326159; called by muse, mutect2, varscan2
- PRB1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 192/806 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.253); catalogued as rs760399871, COSV99555994; called by muse, mutect2, varscan2
- PSD4 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as COSV99831351; called by muse, mutect2, varscan2
- PSIP1 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101050984; called by muse, mutect2, varscan2
- PSMF1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850689; called by muse, mutect2
- PTGS1 | c.1296+2T>C p.X432_splice | Splice Site (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99793401; called by muse, mutect2
- RAB5A | c.328A>T p.R110* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99811124; called by muse, mutect2, varscan2
- RALGAPA1 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.269); catalogued as COSV99355699; called by muse, mutect2, varscan2
- RASL11A | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV99611145; called by muse, mutect2, varscan2
- REXO2 | c.148-1G>C p.X50_splice | Splice Site (SNP) | VAF 18/62 reads (29%) | catalogued as COSV56278128; called by muse, mutect2, varscan2
- RIOK3 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.605); catalogued as COSV100259420; called by muse, mutect2, varscan2
- RPP30 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99520997; called by muse, mutect2, varscan2
- RSPH1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV99370629; called by muse, mutect2, varscan2
- RUNDC3B | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV100407203; called by muse, mutect2, varscan2
- SAMD9L | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100561036; called by muse, mutect2, varscan2
- SCAF1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV62183625; called by muse, mutect2, varscan2
- SEMA4D | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100358646; called by muse, mutect2, varscan2
- SERINC3 | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99667927; called by muse, mutect2, varscan2
- SI | c.2159+1G>A p.X720_splice | Splice Site (SNP) | VAF 52/188 reads (28%) | catalogued as COSV100016648; called by muse, mutect2, varscan2
- SIAH2 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 82/131 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV57262104, COSV57262820; called by muse, mutect2, varscan2
- SIK3 | c.3643G>T p.V1215F (on ENST00000445177 / NM_001366686.2; = p.V1173F on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV99056998; called by muse, mutect2, varscan2
- SLC9B2 | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV100294243, COSV60020106; called by muse, mutect2, varscan2
- SOX9 | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99818651; called by muse, mutect2, varscan2
- SPTLC2 | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99377805; called by muse, mutect2, varscan2
- SRRM3 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100418827; called by muse, mutect2
- SSC4D | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as rs1317732157, COSV99300104; called by muse, mutect2, varscan2
- STAT6 | c.2315G>A p.C772Y | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.365); catalogued as COSV55667327; called by muse, mutect2, varscan2
- STH | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as COSV99291110; called by muse, mutect2, varscan2
- STK19 | c.290T>A p.L97H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV100514805; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2332T>G p.L778V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV100562109; called by muse, mutect2, varscan2
- SYNE1 | c.4231C>G p.Q1411E (on ENST00000367255 / NM_182961.4; = p.Q1418E on NM_033071.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1386998081, COSV55006330, COSV99574077; called by muse, mutect2, varscan2
- TAAR1 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs538751400, COSV99257707; called by muse, mutect2, varscan2
- TAS2R3 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093022; called by muse, mutect2, varscan2
- TAS2R41 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1326807276, COSV101281509, COSV101281518; called by muse, mutect2, varscan2
- TENT5D | c.507T>A p.F169L | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100382887; called by muse, mutect2, varscan2
- TFEB | c.804-1G>C p.X268_splice | Splice Site (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100026389; called by muse, mutect2, varscan2
- TMEM107 | c.315G>A p.W105* (on ENST00000437139 / NM_183065.4; = p.W111* on NM_032354.5) | Nonsense Mutation (SNP) | VAF 58/247 reads (23%) | catalogued as COSV100328805; called by muse, mutect2, varscan2
- TMEM121B | c.1671C>A p.C557* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100083378; called by muse, mutect2
- TMEM131L | c.4607C>T p.S1536F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866485244, COSV99547910; called by muse, mutect2, varscan2
- TMEM200A | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.451); catalogued as COSV99759733; called by muse, mutect2, varscan2
- TMEM268 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99938783; called by muse, mutect2, varscan2
- TOPORS | c.2183C>G p.A728G | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV100859572; called by muse, mutect2, varscan2
- TRAM1 | c.485+1G>A p.X162_splice | Splice Site (SNP) | VAF 52/75 reads (69%) | catalogued as rs556123107, COSV99140787; called by muse, mutect2, varscan2
- TRAPPC12 | c.657G>T p.L219F | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100160824; called by muse, mutect2
- TRIB2 | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV50230181, COSV99331281; called by muse, mutect2, varscan2
- TSPEAR | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV100554923; called by muse, mutect2, varscan2
- TUBGCP2 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1342653473, COSV99428156; called by muse, mutect2, varscan2
- UAP1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99617938; called by muse, mutect2, varscan2
- VAT1 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 56/391 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99887921; called by muse, mutect2, varscan2
- XDH | c.2276G>A p.G759E | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV101052415; called by muse, mutect2, varscan2
- ZBTB39 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100268161; called by muse, varscan2
- ZBTB39 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100268153; called by muse, varscan2
- ZCRB1 | c.446+1G>C p.X149_splice | Splice Site (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99861338; called by muse, mutect2, varscan2
- ZIC5 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV99940691; called by muse, mutect2, varscan2
- ZNF148 | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100642161; called by muse, mutect2, varscan2
- ZNF214 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs1309176100, COSV99547581; called by muse, mutect2, varscan2
- ZNF331 | c.1312T>A p.S438T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99467724; called by muse, mutect2, varscan2
- ZNF354C | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs374746629; called by muse, mutect2, varscan2
- ZNF415 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99701855, COSV99702169; called by muse, mutect2, varscan2
- ZNF471 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as rs372818781; called by muse, mutect2, varscan2
- ZNF606 | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs780776043, COSV58705166; called by muse, mutect2, varscan2
- ZNF91 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100323289; called by muse, mutect2, varscan2
- ZNRF3 | c.1423C>T p.Q475* (on ENST00000544604 / NM_001206998.2; = p.Q375* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV60439498; called by muse, mutect2, varscan2
- CARD6 | c.415_436del p.H139Sfs*49 | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | called by mutect2, pindel, varscan2
- OR10G8 | c.610del p.I204* | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- OR2T35 | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2
- POLR2A | c.2905A>G p.I969V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- POTEA | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- SIDT2 | c.3del p.M1? | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.1671C>T p.T557= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs138310411, COSV99403046; called by muse, mutect2
- ALDH1L1 | c.2418C>T p.F806= | Silent (SNP) | VAF 48/276 reads (17%) | catalogued as rs372361618; called by muse, mutect2, varscan2
- ALOX15B | c.900C>T p.T300= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as COSV101205620, COSV101205677; called by muse, mutect2, varscan2
- ANKS1B | c.441C>T p.L147= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1207457870, COSV61362656; called by muse, mutect2, varscan2
- ANO2 | c.369C>T p.S123= (on ENST00000356134 / NM_001278597.3; = p.S127= on NM_001278596.3) | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100501874, COSV59045527; called by muse, mutect2, varscan2
- ANXA2R | c.36T>G p.A12= | Silent (SNP) | VAF 54/97 reads (56%) | catalogued as COSV100148707; called by muse, mutect2, varscan2
- ASTE1 | c.1317G>A p.R439= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs758588526, COSV99393942; called by muse, mutect2, varscan2
- BROX | c.138G>A p.L46= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV100572299; called by muse, mutect2, varscan2
- CARD17 | c.258G>A p.T86= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs771931690, COSV100995186, COSV100995266; called by muse, mutect2, varscan2
- CDHR2 | c.2760C>T p.D920= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs114350001, COSV56138742; called by muse, mutect2, varscan2
- CTNNB1 | c.60G>C p.A20= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100846406, COSV62728128; called by muse, mutect2, varscan2
- DNAH11 | c.6393G>A p.K2131= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100180170; called by muse, mutect2, varscan2
- DNAH6 | c.1752A>C p.A584= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99408119; called by muse, mutect2, varscan2
- DUOXA2 | c.114C>T p.F38= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99973423; called by muse, mutect2, varscan2
- EHMT1 | c.885C>T p.T295= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100604106; called by muse, mutect2, varscan2
- GCC2 | c.2737C>T p.L913= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV100565581; called by muse, mutect2, varscan2
- H2AC8 | c.303G>C p.V101= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV55127236, COSV55128019; called by muse, mutect2, varscan2
- H4C5 | c.198G>A p.V66= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV63486077, COSV63486239; called by muse, mutect2, varscan2
- HOXD3 | c.939C>A p.A313= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1406693761, COSV50884788, COSV99980354; called by muse, mutect2, varscan2
- ICA1L | c.15G>A p.G5= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs552339558, COSV100841862; called by muse, mutect2, varscan2
- KRT4 | c.945C>T p.Y315= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs778125368, COSV53406546; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRTAP4-1 | c.198C>T p.H66= | Silent (SNP) | VAF 43/74 reads (58%) | catalogued as rs1179636480, COSV100893582; called by muse, varscan2
- LIFR | c.1191T>C p.F397= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV99665022; called by muse, mutect2, varscan2
- LRRC4C | c.1611A>T p.T537= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99539153; called by muse, mutect2, varscan2
- LRRC7 | c.4302T>C p.Y1434= (on ENST00000651989 / NM_001370785.2; = p.Y1354= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/45 reads (80%) | catalogued as COSV99228743; called by muse, mutect2, varscan2
- LYPLAL1 | c.432A>G p.V144= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100859717; called by muse, mutect2, varscan2
- MED20 | c.78G>A p.R26= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99539945; called by muse, mutect2, varscan2
- MKRN2 | c.652T>C p.L218= | Silent (SNP) | VAF 81/92 reads (88%) | catalogued as rs1385469272, COSV99403363; called by muse, mutect2, varscan2
- MYH6 | c.4680C>A p.I1560= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV100676453, COSV100676867; called by muse, mutect2, varscan2
- MYO6 | c.996A>G p.E332= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100889395; called by muse, mutect2, varscan2
- OR10J1 | c.438G>T p.L146= | Silent (SNP) | VAF 66/107 reads (62%) | catalogued as COSV71129495; called by muse, mutect2, varscan2
- PSG1 | c.456C>A p.S152= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV99741045; called by muse, mutect2, varscan2
- RBPMS | c.72G>C p.R24= | Silent (SNP) | VAF 64/101 reads (63%) | catalogued as COSV55124616; called by muse, mutect2, varscan2
- RCVRN | c.324C>G p.L108= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99874308; called by muse, mutect2, varscan2
- RNFT1 | c.199T>C p.L67= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs746007285, COSV99994520; called by muse, mutect2, varscan2
- SLC28A1 | c.1647C>T p.I549= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99723360; called by muse, mutect2, varscan2
- SLF1 | c.2169T>C p.S723= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99476177; called by muse, mutect2, varscan2
- SNTG2 | c.1260G>A p.T420= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs756213124, COSV57977965; called by muse, mutect2, varscan2
- STRAP | c.612A>G p.R204= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV99214876; called by muse, mutect2, varscan2
- TAS2R3 | c.618C>T p.S206= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1204721249, COSV99924516; called by muse, mutect2, varscan2
- TMEM116 | c.660G>A p.Q220= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100702249; called by muse, mutect2, varscan2
- TRIM42 | c.451C>A p.R151= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as rs771456077, COSV53880832, COSV53887344; called by muse, mutect2, varscan2
- UBE3B | c.114C>T p.A38= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as COSV99784306; called by muse, mutect2, varscan2
- USP13 | c.1041C>T p.L347= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV99831568; called by muse, mutect2, varscan2
- USP29 | c.1782C>A p.P594= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99518439; called by muse, mutect2, varscan2
- WDR25 | c.1290C>T p.P430= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100092098; called by muse, mutect2, varscan2
- ZNF415 | c.1383C>T p.I461= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as COSV99701850; called by muse, mutect2, varscan2
- ZNF804B | c.1662G>A p.L554= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV60848989, COSV60851885; called by muse, mutect2, varscan2
- ZNF836 | c.2791C>T p.L931= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100441153; called by muse, varscan2
- BCL11A | c.386-6373G>C | Intron (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100186244, COSV59625940; called by muse, mutect2, varscan2
- BIRC8 | n.1472G>A | RNA (SNP) | VAF 16/105 reads (15%) | catalogued as COSV101461353; called by muse, mutect2, varscan2
- GCK | c.*2_*3del | 3'UTR (DEL) | VAF 18/30 reads (60%) | called by pindel, varscan2
- MIR92A1 | n.44A>G | RNA (SNP) | VAF 92/112 reads (82%) | catalogued as rs374040259; called by muse, mutect2, varscan2
- PXN | c.831+2215C>G | Intron (SNP) | VAF 55/107 reads (51%) | called by muse, mutect2, varscan2
- SNORD115-14 | n.34A>G | RNA (SNP) | VAF 56/275 reads (20%) | called by muse, mutect2, varscan2
- SYTL2 | c.1615+1298G>A | Intron (SNP) | VAF 36/76 reads (47%) | catalogued as rs376203930; called by muse, mutect2, varscan2
